CCDI case PBBVYF — CCDI-MCI: Molecular Characterization Initiative (MCI)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Neoplasms, NOS; Primary site: Brain.
https://portal.gdc.cancer.gov/cases/25028564-0130-4aeb-ae04-99f3bdee3180

Demographics
Sex at birth: male; Race: white; Vital status: Alive.

Diagnoses (1)
1. Choroid plexus papilloma, NOS: ICD-O-3 morphology code: 9390/0; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 0.6 years (216 days).

Biospecimens (2 samples)
- Sample 0DIMWT: Tissue type: Normal; Specimen type: Peripheral Whole Blood.
- Sample 0DIMX7: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
